Somatic mutation profile of tumor specimen C3L-02800-01 (aliquot CPT0186900011) from CPTAC case C3L-02800, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1; Tumor grade: G2; Age at diagnosis: 62.7 years (22,902 days).
Specimen C3L-02800-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 338ffa74-0a62-4687-b555-87c9aa5699fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02800-71 (Blood Derived Normal), aliquot CPT0186930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1727c346-de73-47ed-8182-8377adea0f62

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 3, Frame Shift Del 2, 3'UTR 2, 5'UTR 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 18/91 reads (20%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | hotspot (GDC flag); catalogued as rs1554897280, CD004539, CS110217, CS991490, CS992480, COSV64288452, COSV64288759, COSV64291888, COSV64298333; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 188/479 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs45517258, CM023179, CM981950, COSV54765887; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABLIM2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs371815593; called by muse, mutect2, varscan2
- CCDC30 | c.2009G>T p.R670L (on ENST00000340612; = p.R627L on NM_001080850.3) | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.332); catalogued as rs867134188, COSV59606199; called by muse, mutect2
- CELF4 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs922164395; called by muse, mutect2, varscan2
- CILP2 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770273408; called by muse, mutect2, varscan2
- CNTNAP2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 78/372 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs752756517, COSV62253518, COSV62260875; called by muse, mutect2, varscan2
- FGG | c.637T>A p.S213T | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as CD1511835; called by muse, mutect2, varscan2
- GPR174 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 42/220 reads (19%) | catalogued as rs753195995, COSV99338073; called by muse, mutect2, varscan2
- IQCE | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs377697366; called by muse, mutect2
- LZTR1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53152072; called by muse, mutect2, varscan2
- MGA | c.7307G>A p.R2436H (on ENST00000219905 / NM_001164273.1; = p.R2227H on NM_001080541.2) | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1054243525, COSV54949857; called by muse, mutect2, varscan2
- MIA2 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.461); catalogued as rs942254770, COSV54484273; called by muse, mutect2
- MYCBP2 | c.12053G>T p.R4018I (on ENST00000357337; = p.R4056I on NM_015057.5) | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62017392, COSV62021810, COSV62030781; called by mutect2, varscan2
- NECAB2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs748924576, COSV100533818; called by muse, mutect2, varscan2
- NPBWR1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV100488338; called by muse, mutect2, varscan2
- PCDHA8 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs200720426, COSV65323235; called by muse, mutect2, varscan2
- PLXNB2 | c.5443G>A p.A1815T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs748967251, COSV63779930; called by muse, mutect2, varscan2
- RRAS2 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56329798, COSV56330700, COSV56332575; called by muse, mutect2, varscan2
- TNNC1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752100917, COSV51767820; called by muse, mutect2
- TSHZ3 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs768899742, COSV53683169; called by mutect2, varscan2
- UBR4 | c.13142C>T p.P4381L | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144615268; called by muse, mutect2, varscan2
- UBXN4 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771687405; called by muse, mutect2, varscan2
- ZNF131 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs1328136195; called by muse, mutect2, varscan2
- ANKRD63 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- ARID1A | c.5030dup p.S1678Vfs*20 | Frame Shift Ins (INS) | VAF 24/206 reads (12%) | called by mutect2, pindel, varscan2
- CBARP | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CDC73 | c.1261_1262del p.V421Yfs*5 | Frame Shift Del (DEL) | VAF 30/224 reads (13%) | called by pindel, varscan2
- CDH9 | c.1286G>C p.R429P | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CEP152 | c.2888A>C p.E963A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CLIP1 | c.4252T>G p.Y1418D (on ENST00000620786 / NM_001247997.1; = p.Y1407D on NM_002956.2) | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEPDC1B | c.668G>C p.S223T | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FCAR | c.766A>G p.N256D | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- FOXD4L3 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by mutect2, varscan2
- KDM5C | c.4345C>T p.R1449W | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP4-9 | c.131G>T p.C44F | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRR1 | c.217T>C p.F73L | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- M1AP | c.1417_1422+6del p.X473_splice | Splice Site (DEL) | VAF 19/140 reads (14%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NAA15 | c.1410_1410+10del p.X470_splice | Splice Site (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- NOC2L | c.1958del p.M653Rfs*18 | Frame Shift Del (DEL) | VAF 37/227 reads (16%) | called by mutect2, pindel, varscan2
- PFKM | c.1135A>C p.M379L | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- PLS3 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- PPP1CB | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); called by muse, varscan2
- PRRG4 | c.383T>G p.L128W | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- RIC3 | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- RNF214 | c.1189_1193dup p.E398Dfs*6 | Frame Shift Ins (INS) | VAF 29/207 reads (14%) | called by mutect2, pindel, varscan2
- SPTA1 | c.4687A>T p.N1563Y | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- STAT3 | c.1918T>C p.Y640H | Missense Mutation (SNP) | VAF 63/317 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAOK1 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- TLR7 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TP53BP1 | c.5353G>A p.G1785S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK3 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF544 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 100/495 reads (20%) | called by muse, mutect2, varscan2
- ZNF574 | c.160_167dup p.L57Gfs*2 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- ZYX | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ADAMTS10 | c.1557G>A p.T519= | Silent (SNP) | VAF 69/365 reads (19%) | catalogued as rs782214057, COSV54356151; called by muse, mutect2, varscan2
- ADCY2 | c.3088A>C p.R1030= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- CASZ1 | c.4509C>T p.F1503= | Silent (SNP) | VAF 49/204 reads (24%) | catalogued as rs957169851; called by muse, mutect2, varscan2
- DHCR24 | c.117C>T p.L39= | Silent (SNP) | VAF 90/478 reads (19%) | catalogued as rs770259892; called by muse, mutect2, varscan2
- GDF2 | c.186G>A p.V62= | Silent (SNP) | VAF 69/159 reads (43%) | called by muse, mutect2, varscan2
- HSPG2 | c.2613C>T p.P871= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs373732798; called by muse, mutect2, varscan2
- IRAG1 | c.2091C>T p.S697= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs778306727; called by muse, mutect2, varscan2
- IRX2 | c.1089C>T p.T363= | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as rs377008864; called by muse, mutect2, varscan2
- PCDHA1 | c.1314G>A p.T438= | Silent (SNP) | VAF 100/443 reads (23%) | catalogued as rs782630846; called by muse, mutect2, varscan2
- POM121C | c.3312C>T p.T1104= (on ENST00000607367; = p.T862= on NM_001099415.3) | Silent (SNP) | VAF 46/279 reads (16%) | catalogued as rs781799072, COSV99993128; called by muse, mutect2, varscan2
- PRRT1 | c.402G>A p.P134= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- RORC | c.828C>T p.S276= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs150459022; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMCC2 | c.1473C>T p.S491= | Silent (SNP) | VAF 42/164 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.78132C>T p.V26044= (on ENST00000591111; = p.V18620= on NM_003319.4) | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs758110575, COSV60246454; called by muse, mutect2, varscan2
- WNT5B | c.873C>T p.N291= | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as rs754560999, COSV60197490; called by muse, mutect2, varscan2
- XK | c.1272T>C p.S424= | Silent (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- CALCR | c.51+2912G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- CDH8 | c.*5749T>A | 3'UTR (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- INTS1 | c.-66_-64dup | 5'UTR (INS) | VAF 48/336 reads (14%) | catalogued as rs769212671; called by mutect2, varscan2
- PEX19 | c.*2261G>T | 3'UTR (SNP) | VAF 54/260 reads (21%) | called by muse, mutect2, varscan2
- UGP2 | c.-24G>T | 5'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
